Somatic mutation profile of tumor specimen TCGA-YG-AA3O-06A (aliquot TCGA-YG-AA3O-06A-11D-A38G-08) from TCGA case TCGA-YG-AA3O, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.5 years (23,907 days).
Specimen TCGA-YG-AA3O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20537ef8-116f-4429-82b7-648f09d70878.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YG-AA3O-10A (Blood Derived Normal), aliquot TCGA-YG-AA3O-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a12b60b2-9751-4ce6-8350-9f961fb419b7

The open-access MAF lists 1,346 somatic variants for this specimen: 902 protein-altering or splice-affecting, 413 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 816, Silent 413, Nonsense Mutation 49, Splice Site 15, RNA 13, Intron 11, Splice Region 10, Frame Shift Del 5, In Frame Del 3, 3'UTR 3, 5'Flank 3, Frame Shift Ins 2.

Variants (750 of 1,346; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/136 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/134 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GPC6 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs121908440, CM093495, COSV100988064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 36/67 reads (54%) | catalogued as rs775112258, CM1311877, COSV70350217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7234G>A p.A2412T | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.574); catalogued as COSV101446736; called by muse, mutect2
- ABCA4 | c.6283G>A p.D2095N | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933020; called by muse, mutect2, varscan2
- ABCB11 | c.2449G>A p.G817R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99791510; called by muse, mutect2, varscan2
- ABCD2 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100429139; called by muse, mutect2, varscan2
- ABCD4 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV53991897; called by muse, mutect2, varscan2
- ABRA | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as COSV100357456; called by muse, varscan2
- ACAN | c.4645C>T p.P1549S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV61366563; called by muse, mutect2, varscan2
- ACOT11 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs781051947, COSV100650455; called by muse, mutect2, varscan2
- ACP6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs978886014, COSV65076275; called by muse, mutect2, varscan2
- ACR | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99334343; called by muse, varscan2
- ACSBG2 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.353); catalogued as COSV99397165; called by muse, mutect2, varscan2
- ACSF2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366043; called by muse, mutect2
- ACSM2A | c.1505G>A p.G502E (on ENST00000219054; = p.G423E on NM_001308169.2) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1177435625, COSV99524867; called by muse, mutect2, varscan2
- ACSS3 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201300759, COSV99698265; called by muse, mutect2, varscan2
- ACTR10 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99580888; called by muse, mutect2, varscan2
- ACVR1C | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99694322; called by muse, mutect2, varscan2
- ADAM18 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.651); catalogued as COSV99694848; called by muse, varscan2
- ADAM18 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV99694849; called by muse, varscan2
- ADAMTS12 | c.2027T>C p.V676A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100710259; called by muse, mutect2, varscan2
- ADAMTS14 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100941333; called by muse, mutect2, varscan2
- ADAMTS19 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs1305534749, COSV99176302; called by muse, mutect2, varscan2
- ADAMTS2 | c.2842G>A p.D948N | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.04); catalogued as rs758419331, COSV52363448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS7 | c.5021G>A p.G1674D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV101183008; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99440813; called by muse, mutect2, varscan2
- ADARB2 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.149); catalogued as COSV101186597; called by muse, mutect2, varscan2
- ADCY8 | c.3010G>A p.G1004R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99650680; called by muse, mutect2, varscan2
- ADGRE3 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs149254238, COSV99506422; called by muse, mutect2, varscan2
- ADGRE3 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs774415927, COSV99505781; called by muse, mutect2, varscan2
- ADGRF1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99346930; called by muse, mutect2, varscan2
- ADGRL1 | c.1702G>A p.G568R (on ENST00000340736 / NM_001008701.3; = p.G563R on NM_014921.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100529247; called by muse, mutect2, varscan2
- ADGRV1 | c.4198T>C p.Y1400H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101315463; called by muse, mutect2
- ADGRV1 | c.9926C>T p.P3309L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1254801749, COSV101315469; called by muse, mutect2, varscan2
- ADH1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV52924354; called by muse, mutect2, varscan2
- AEBP1 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV56259009, COSV99788391; called by muse, mutect2, varscan2
- AFF1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335382724, COSV100320194; called by muse, mutect2, varscan2
- AGO3 | c.1326A>T p.Q442H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99867961; called by muse, mutect2, varscan2
- AGR2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101290800; called by muse, mutect2, varscan2
- AGTR2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV100903529; called by muse, mutect2, varscan2
- AHNAK | c.8236C>T p.P2746S | Missense Mutation (SNP) | VAF 87/133 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV99945484; called by muse, mutect2, varscan2
- AHNAK2 | c.12916C>T p.P4306S | Missense Mutation (SNP) | VAF 180/386 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV60929657; called by muse, mutect2, varscan2
- AKAP1 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1344735368, COSV100027711; called by muse, mutect2, varscan2
- AKR1D1 | c.735C>G p.N245K | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99652813; called by muse, mutect2, varscan2
- ALK | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101201160, COSV66559733; called by muse, mutect2, varscan2
- ALS2 | c.4609C>T p.L1537F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV51887428; called by muse, mutect2, varscan2
- ALX4 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100240876; called by muse, mutect2, varscan2
- AMDHD1 | c.248T>G p.L83W | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99900185; called by muse, mutect2, varscan2
- ANAPC2 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100118870; called by mutect2, varscan2
- ANGPTL2 | c.1477C>A p.H493N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99400763; called by muse, mutect2, varscan2
- ANK2 | c.4407C>T p.I1469= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as rs1355288561, COSV100004933, COSV52153997; called by muse, mutect2, varscan2
- ANK3 | c.5441C>T p.S1814F | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV99778216; called by muse, mutect2, varscan2
- ANK3 | c.3017G>A p.R1006K (on ENST00000280772 / NM_001320874.2; = p.R140K on NM_001149.3) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99778218; called by muse, mutect2, varscan2
- ANK3 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.333); catalogued as rs538354013, COSV55048293; called by muse, mutect2, varscan2
- ANK3 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1485831548, COSV55059318; called by muse, mutect2, varscan2
- ANKIB1 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56060377; called by muse, mutect2
- ANKRD13A | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765416553, COSV99923830; called by muse, mutect2, varscan2
- ANKRD17 | c.3950C>T p.P1317L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100428537; called by muse, mutect2, varscan2
- ANKRD30A | c.304C>T p.L102F (on ENST00000611781; = p.L46F on NM_052997.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV100652886; called by muse, mutect2, varscan2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, mutect2, varscan2
- ANO1 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796915; called by muse, mutect2, varscan2
- ANO4 | c.1334G>T p.W445L (on ENST00000392977 / NM_001286615.2; = p.W410L on NM_178826.4) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100151276, COSV54603359; called by muse, mutect2, varscan2
- ANO4 | c.1655G>A p.G552E (on ENST00000392977 / NM_001286615.2; = p.G517E on NM_178826.4) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100151872; called by muse, mutect2, varscan2
- ANPEP | c.2777A>G p.E926G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100262579; called by muse, mutect2, varscan2
- ANPEP | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV100262581; called by muse, mutect2, varscan2
- AOAH | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs768074623, COSV51746075, COSV99332047; called by muse, mutect2, varscan2
- AP1M2 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51568867, COSV99140727; called by muse, mutect2, varscan2
- AP4E1 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV99956257; called by muse, mutect2, varscan2
- APAF1 | c.2206C>T p.R736* (on ENST00000551964 / NM_181861.2; = p.R725* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as rs150355642; called by muse, mutect2, varscan2
- APC | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.277); catalogued as COSV57399079; called by muse, mutect2, varscan2
- APMAP | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as COSV99468148; called by muse, mutect2, varscan2
- APOBEC3G | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101349039; called by muse, mutect2, varscan2
- APOF | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV100028955, COSV58474483; called by muse, mutect2, varscan2
- ARAP3 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99499300; called by muse, mutect2, varscan2
- ARFGEF3 | c.4969G>A p.E1657K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs368581445; called by muse, mutect2, varscan2
- ARHGAP10 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1348240844, COSV100330869; called by muse, mutect2, varscan2
- ARHGAP17 | c.2003C>T p.P668L (on ENST00000289968 / NM_001006634.3; = p.P590L on NM_018054.6) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV99252849; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARHGAP30 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100920132; called by muse, mutect2, varscan2
- ARMC4 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV53463031; called by muse, mutect2, varscan2
- ARMCX5 | c.849del p.K283Nfs*25 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs749534706; called by pindel, varscan2
- ASB10 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV99318128; called by muse, mutect2
- ASTN1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as rs267598198, COSV56067864, COSV99920404; called by muse, mutect2, varscan2
- ASTN2 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100524615; called by muse, mutect2, varscan2
- ATG5 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100576385; called by muse, mutect2, varscan2
- ATL1 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100612901; called by muse, mutect2, varscan2
- ATP1A3 | c.2023G>A p.D675N (on ENST00000545399 / NM_001256214.2; = p.D662N on NM_152296.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100131933; called by muse, mutect2, varscan2
- ATP6V0D2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV99571284; called by muse, mutect2, varscan2
- ATP8A2 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679891; called by muse, mutect2, varscan2
- AXIN2 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100195885, COSV61061159; called by muse, mutect2, varscan2
- BANK1 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100535838; called by muse, mutect2, varscan2
- BAP1 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56236638, COSV99963355; called by muse, mutect2, varscan2
- BATF | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as COSV99708688; called by muse, mutect2, varscan2
- BCR | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100005938; called by muse, mutect2, varscan2
- BEND2 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 119/152 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as rs756416335, COSV66217700; called by muse, mutect2, varscan2
- BEND4 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs373680999; called by muse, mutect2, varscan2
- BIN1 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1391982523, COSV99387461; called by muse, mutect2, varscan2
- BMP10 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770263; called by muse, mutect2, varscan2
- BMP15 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV53141764; called by muse, mutect2
- BMPR2 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV101001222; called by muse, mutect2, varscan2
- BNIP5 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1460800400, COSV101465108; called by muse, mutect2, varscan2
- BNIP5 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs1156713974, COSV101465109; called by muse, mutect2, varscan2
- BRINP2 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV64176813, COSV64179229; called by muse, mutect2, varscan2
- C1QTNF9 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV100129773; called by muse, mutect2, varscan2
- C1QTNF9B | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101158523; called by muse, mutect2, varscan2
- C8orf34 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs867335537, COSV57400749, COSV57402183; called by muse, mutect2, varscan2
- CA8 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs749446493, COSV58771282; called by muse, mutect2, varscan2
- CACNA1E | c.6106G>A p.E2036K (on ENST00000367573 / NM_001205293.3; = p.E1993K on NM_000721.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as COSV100701275; called by muse, mutect2, varscan2
- CACNA1G | c.4864G>A p.G1622R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1299615800, COSV100661075, COSV61722641; called by muse, mutect2, varscan2
- CACNA2D1 | c.3302G>A p.R1101H (on ENST00000356253 / NM_001366867.1; = p.R1089H on NM_000722.4) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.006); catalogued as rs143631985, COSV100665755, COSV100666394; called by muse, mutect2, varscan2
- CACNA2D2 | c.1260+1G>A p.X420_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | catalogued as COSV56560968; called by muse, mutect2, varscan2
- CACNB3 | c.471A>T p.L157= | Splice Region (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99974659; called by muse, mutect2, varscan2
- CADM2 | c.749C>T p.S250F (on ENST00000407528 / NM_001167674.2; = p.S252F on NM_153184.4) | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV101052746; called by muse, mutect2, varscan2
- CAMK1D | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV101123420; called by muse, mutect2, varscan2
- CAPN13 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99699737; called by muse, mutect2, varscan2
- CAPN3 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV99782137; called by muse, mutect2, varscan2
- CAPZA1 | c.694A>T p.I232L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99582845; called by muse, mutect2, varscan2
- CARNS1 | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1275266339, COSV100321761; called by muse, mutect2, varscan2
- CARS1 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1314994437, COSV99541942; called by muse, mutect2, varscan2
- CASR | c.1483G>A p.E495K (on ENST00000490131; = p.E572K on NM_000388.4) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99948439; called by muse, mutect2, varscan2
- CATSPERB | c.2984G>A p.R995K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1281328193, COSV99830783; called by muse, mutect2, varscan2
- CATSPERD | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV58464771; called by muse, mutect2, varscan2
- CCDC103 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1477668851; called by muse, mutect2, varscan2
- CCDC172 | c.266T>G p.M89R | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100319636; called by muse, mutect2, varscan2
- CCDC40 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV100884227; called by muse, mutect2, varscan2
- CCDC73 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100066421; called by muse, mutect2, varscan2
- CCDC93 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60119648; called by mutect2, varscan2
- CCKAR | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99810089; called by muse, mutect2, varscan2
- CCKBR | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100582704; called by muse, mutect2, varscan2
- CCNB3 | c.3485C>T p.A1162V | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99328413; called by muse, mutect2, varscan2
- CCNE1 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.492); catalogued as rs1462598632, COSV99388171; called by muse, mutect2, varscan2
- CCNE2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100353616, COSV100353769; called by muse, mutect2, varscan2
- CCR8 | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV100413004, COSV100413140; called by muse, mutect2, varscan2
- CD163 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs763870982, COSV63129524; called by muse, mutect2, varscan2
- CD163L1 | c.4138C>T p.L1380F | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV100549642, COSV58024022; called by muse, mutect2, varscan2
- CD163L1 | c.3905G>A p.G1302D | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549643; called by muse, mutect2, varscan2
- CD200R1L | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as COSV68003930, COSV68004269; called by muse, mutect2, varscan2
- CD300C | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV58169913; called by muse, mutect2
- CDA | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100906233, COSV66751919; called by muse, mutect2, varscan2
- CDH10 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV52581403; called by muse, mutect2, varscan2
- CDH23 | c.8317G>A p.E2773K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs765697060, COSV99818757; called by muse, mutect2, varscan2
- CDH7 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.468); catalogued as COSV100541395; called by muse, mutect2, varscan2
- CDH8 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.469); catalogued as COSV54852598; called by muse, mutect2, varscan2
- CDH9 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV50317389, COSV99141488; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1226T>G p.V409G (on ENST00000357886 / NM_001365728.1; = p.V395G on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100211857; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100575061; called by muse, mutect2
- CDYL | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100188679; called by muse, mutect2, varscan2
- CEMIP2 | c.1979+2T>A p.X660_splice | Splice Site (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100987219; called by muse, mutect2, varscan2
- CEP83 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs867235531, COSV100352631; called by muse, mutect2, varscan2
- CES3 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100309789; called by muse, mutect2, varscan2
- CES4A | c.1454T>A p.M485K (on ENST00000648724 / NM_001364782.1; = p.M387K on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100109935; called by muse, mutect2, varscan2
- CFAP52 | c.855G>A p.K285= | Splice Region (SNP) | VAF 22/35 reads (63%) | catalogued as rs1352129023, COSV55349357; called by muse, mutect2, varscan2
- CFAP54 | c.5110G>A p.D1704N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.172); catalogued as COSV100732930; called by muse, mutect2, varscan2
- CHD3 | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100390663; called by muse, mutect2, varscan2
- CHI3L1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs141218577; called by muse, mutect2, varscan2
- CHRM3 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV55089455; called by muse, mutect2, varscan2
- CHRM3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs780261877, COSV99697438; called by muse, mutect2, varscan2
- CHRM3 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV55085937; called by muse, mutect2, varscan2
- CIITA | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV100161333, COSV100161716; called by muse, mutect2
- CLEC3A | c.205G>A p.E69K (on ENST00000651443; = p.E60K on NM_005752.6) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55219916; called by muse, mutect2, varscan2
- CLEC6A | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV101165612; called by muse, mutect2, varscan2
- CLIP2 | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56283581; called by muse, mutect2, varscan2
- CLN8 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794727299, COSV100485968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866552463, COSV101515528; called by muse, mutect2, varscan2
- CLYBL | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59224603; called by muse, mutect2, varscan2
- CNPPD1 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV99840855; called by muse, mutect2, varscan2
- CNTNAP2 | c.2956G>A p.G986S | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs751542883, COSV62168175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP4 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs1245559508, COSV100269286; called by muse, mutect2, varscan2
- COL28A1 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258294; called by muse, mutect2, varscan2
- COL28A1 | c.324T>G p.F108L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV101258295; called by muse, mutect2, varscan2
- COL5A1 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100879466; called by muse, mutect2, varscan2
- COL5A1 | c.4348G>A p.G1450S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100879467; called by muse, mutect2, varscan2
- COL5A2 | c.3310-1G>A p.X1104_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100880001; called by muse, mutect2, varscan2
- COL5A2 | c.2873C>A p.P958Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.641); catalogued as COSV100880003; called by muse, mutect2, varscan2
- COL5A3 | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99318201; called by muse, mutect2
- COX19 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.749); catalogued as COSV100700395; called by muse, mutect2, varscan2
- CPAMD8 | c.408G>A p.K136= (on ENST00000651564; = p.K89= on NM_015692.5) | Splice Region (SNP) | VAF 35/160 reads (22%) | catalogued as COSV99358939; called by muse, mutect2, varscan2
- CPLX1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100408197; called by muse, mutect2, varscan2
- CPXM1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs758525497, COSV101013675, COSV66044804; called by muse, mutect2, varscan2
- CR2 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771838431, COSV100889526; called by muse, mutect2, varscan2
- CR2 | c.2726-1G>A p.X909_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100889527; called by muse, mutect2, varscan2
- CRB1 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as rs1324068019, COSV100958321; called by muse, mutect2, varscan2
- CRB2 | c.2090C>G p.T697R | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV100749516; called by muse, mutect2, varscan2
- CRIM1 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99752338; called by muse, mutect2, varscan2
- CRTC1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1428837465, COSV100119017; called by muse, mutect2, varscan2
- CRTC1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100119018; called by muse, mutect2, varscan2
- CSF2RB | c.1407-1G>A p.X469_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99453248; called by muse, mutect2, varscan2
- CSMD1 | c.1591C>T p.P531S (on ENST00000520002; = p.P530S on NM_033225.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59326943; called by muse, mutect2
- CTCFL | c.1540T>G p.F514V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99712098; called by muse, varscan2
- CTNNA2 | c.2383G>A p.V795M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559432, COSV58159510; called by muse, mutect2, varscan2
- CTNND2 | c.3084+1G>A p.X1028_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100471546; called by muse, mutect2, varscan2
- CUEDC1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs149814069; called by muse, mutect2, varscan2
- CUX2 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV99918574; called by mutect2, varscan2
- CYP2C19 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64907874; called by muse, mutect2, varscan2
- CYP3A4 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100315431; called by muse, mutect2, varscan2
- CYP4F12 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV100215589, COSV61175676; called by muse, mutect2, varscan2
- CYP4F12 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61176961; called by muse, mutect2, varscan2
- CYP4F3 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55411523; called by muse, mutect2, varscan2
- DAB1 | c.878C>T p.S293F (on ENST00000371231; = p.S260F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100976133, COSV64689897; called by muse, mutect2, varscan2
- DBF4B | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs375849896; called by muse, mutect2, varscan2
- DCAF1 | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs782805061, COSV60043152; called by muse, mutect2, varscan2
- DCAF8L1 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | catalogued as rs201455864, COSV71595237; called by muse, mutect2, varscan2
- DCUN1D3 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.514); catalogued as COSV60955429; called by muse, mutect2, varscan2
- DDX24 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1274665922, COSV100427806; called by muse, mutect2, varscan2
- DDX46 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100844846; called by muse, mutect2, varscan2
- DDX60 | c.1485A>T p.E495D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101190232; called by muse, mutect2
- DDX60 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101190234; called by muse, mutect2
- DENND1C | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780186122, COSV100375156, COSV100375200; called by muse, mutect2, varscan2
- DEPTOR | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV99637811; called by muse, mutect2, varscan2
- DGKI | c.2398T>A p.S800T | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.6); PolyPhen benign (0.047); catalogued as COSV55949199; called by muse, mutect2, varscan2
- DIS3L | c.1747C>T p.R583* (on ENST00000319212 / NM_001143688.3; = p.R500* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as rs777537433, COSV59911459; called by muse, mutect2, varscan2
- DIS3L2 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99805439; called by muse, mutect2, varscan2
- DISP3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV99607286; called by muse, mutect2, varscan2
- DLEC1 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1465304584, COSV57305827; called by muse, mutect2, varscan2
- DLG1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1451447881, COSV100014576; called by muse, mutect2, varscan2
- DLG2 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781596546, COSV99712533; called by muse, mutect2, varscan2
- DLGAP1 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1410384061, COSV100227912; called by muse, mutect2, varscan2
- DLGAP4 | c.2504C>T p.S835F (on ENST00000339266 / NM_001365621.1; = p.S832F on NM_014902.6) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV100210789; called by muse, mutect2, varscan2
- DMBT1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780912281, COSV57532698; called by muse, mutect2, varscan2
- DNAH1 | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101324650; called by muse, mutect2, varscan2
- DNAH1 | c.10418C>T p.S3473F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70226877; called by muse, mutect2, varscan2
- DNAH11 | c.9187G>A p.E3063K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100176947; called by muse, mutect2, varscan2
- DNAH17 | c.9719G>A p.G3240D | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101101376; called by muse, mutect2, varscan2
- DNAH17 | c.7042G>A p.E2348K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350731550, COSV101101379; called by muse, mutect2, varscan2
- DNAH5 | c.13513G>A p.G4505S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54208187, COSV54233072; called by muse, mutect2, varscan2
- DNAH7 | c.6853G>A p.E2285K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV56790894; called by muse, mutect2, varscan2
- DNAH7 | c.5000C>T p.S1667F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100413781; called by muse, mutect2, varscan2
- DNAH8 | c.7735C>T p.R2579* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as rs763871040, COSV100543222; called by muse, mutect2, varscan2
- DNAH8 | c.10261C>T p.P3421S | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953211968, COSV59447877; called by muse, mutect2, varscan2
- DNAH9 | c.4180G>A p.G1394S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as rs546724157, COSV99303952; called by muse, mutect2, varscan2
- DNAI1 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755853256, COSV99646547; called by muse, mutect2, varscan2
- DNAJB1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV54317227, COSV54317299; called by muse, mutect2, varscan2
- DNAJC5B | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99395418; called by muse, mutect2, varscan2
- DOCK2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910222; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DRD4 | c.1076G>A p.W359* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs1316423953, COSV99448420; called by muse, mutect2, varscan2
- DSC2 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99199462; called by muse, mutect2, varscan2
- DSCAM | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs367690354, COSV68648441; called by muse, mutect2, varscan2
- E2F7 | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV59743953; called by muse, mutect2, varscan2
- EBAG9 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as CM124441, COSV100520744; called by muse, mutect2, varscan2
- ECRG4 | c.286-1G>A p.X96_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99430195; called by muse, mutect2, varscan2
- EDN3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV100284770; called by muse, mutect2, varscan2
- EGFLAM | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV59320213; called by muse, mutect2, varscan2
- EIF4G1 | c.2980C>T p.R994* (on ENST00000346169 / NM_198241.3; = p.R799* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 44/139 reads (32%) | catalogued as COSV100071416; called by muse, mutect2, varscan2
- ELOA2 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs760844696, COSV55294978; called by muse, mutect2, varscan2
- EML1 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs757227237, COSV51752471; called by muse, mutect2, varscan2
- ENAM | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as rs766044001, COSV101252914; called by muse, mutect2, varscan2
- ENC1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.876); catalogued as rs866443122, COSV100187865; called by muse, mutect2, varscan2
- ENPEP | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as COSV54449878, COSV99486993; called by muse, mutect2, varscan2
- ENPP3 | c.2168-1G>A p.X723_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV62956773; called by muse, mutect2, varscan2
- EPB41L2 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100440217; called by muse, mutect2, varscan2
- EPYC | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763496574, COSV99664473; called by muse, mutect2, varscan2
- EPYC | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV99664474; called by muse, mutect2, varscan2
- ERC2 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55606980; called by muse, mutect2
- ERICH3 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs267598720, COSV58611092; called by muse, mutect2, varscan2
- ERN2 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99890542; called by muse, mutect2, varscan2
- ESF1 | c.1994T>C p.V665A | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs755499849, COSV99176256; called by muse, mutect2, varscan2
- EVPL | c.4097C>T p.P1366L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs755813124, COSV100043934; called by muse, mutect2, varscan2
- EXOSC10 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442117; called by muse, mutect2, varscan2
- F10 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV65023487; called by muse, mutect2, varscan2
- F2 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs200969932, COSV61314728, COSV61318280; called by muse, mutect2, varscan2
- F2R | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV59929460; called by muse, mutect2, varscan2
- F5 | c.2947G>A p.G983R | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100888874; called by muse, mutect2, varscan2
- FAM153B | c.469C>T p.H157Y (on ENST00000253490; = p.H80Y on NM_001265615.1) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.123); catalogued as COSV99498718; called by muse, varscan2
- FAM47C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100792269; called by muse, mutect2, varscan2
- FAM9C | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100452754; called by muse, mutect2, varscan2
- FAT3 | c.10927G>A p.E3643K | Missense Mutation (SNP) | VAF 131/199 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99961570; called by muse, mutect2, varscan2
- FAT3 | c.11180G>T p.R3727I | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV53150959; called by muse, mutect2, varscan2
- FAT4 | c.11660C>T p.S3887L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); catalogued as COSV58674066; called by muse, mutect2, varscan2
- FBXO47 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1305239547, COSV100960541; called by muse, mutect2, varscan2
- FCRL3 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as COSV100942808, COSV63840826; called by muse, mutect2, varscan2
- FCRL5 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100708508; called by muse, mutect2, varscan2
- FLRT2 | c.1622T>A p.F541Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs770570149, COSV100419967; called by muse, mutect2, varscan2
- FMO1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772867301, COSV100707987, COSV61446650; called by muse, mutect2, varscan2
- FOXO1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as COSV101091754; called by muse, mutect2, varscan2
- FOXO1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753755451, COSV101091755; called by muse, mutect2, varscan2
- FREM1 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV101085723, COSV66517749, COSV66518799; called by muse, mutect2, varscan2
- FRK | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs753596132, COSV73384053; called by muse, mutect2, varscan2
- FRMD1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV51963299; called by muse, mutect2, varscan2
- FRMPD1 | c.273C>G p.H91Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.695); catalogued as COSV100733484, COSV63383722; called by muse, mutect2, varscan2
- FRMPD2 | c.1441A>G p.N481D | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.028); catalogued as COSV100563484; called by muse, mutect2, varscan2
- FSHB | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV54221544; called by muse, mutect2, varscan2
- FST | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1259308770, COSV99887005; called by muse, varscan2
- FST | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56815477; called by muse, varscan2
- FSTL5 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); catalogued as COSV60180843; called by muse, mutect2, varscan2
- GABRA2 | c.946T>G p.F316V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100733803; called by muse, mutect2, varscan2
- GABRG3 | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.9); catalogued as COSV100404733; called by muse, mutect2, varscan2
- GAD1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100713748; called by muse, mutect2
- GALNT13 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV67236375; called by muse, mutect2, varscan2
- GATA3 | c.335G>A p.W112* | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100650804; called by muse, mutect2, varscan2
- GCOM1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV99984574, COSV99985181; called by muse, mutect2, varscan2
- GCSAML | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100825879, COSV63579149; called by muse, mutect2
- GDF5 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1480820638, COSV65499677; called by muse, mutect2, varscan2
- GH2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60426144; called by muse, mutect2, varscan2
- GK2 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774708528, COSV62626317; called by muse, mutect2, varscan2
- GLDN | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs754088387, COSV100117477; called by muse, mutect2
- GLIS3 | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100173242; called by muse, mutect2, varscan2
- GLRA3 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV56867173; called by muse, mutect2, varscan2
- GNA15 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99505036; called by muse, mutect2, varscan2
- GOLGA6A | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV99296985; called by muse, mutect2, varscan2
- GP2 | c.1376T>G p.L459R (on ENST00000381362 / NM_001007240.3; = p.L456R on NM_001502.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100221243; called by muse, mutect2, varscan2
- GPATCH1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99403726; called by muse, mutect2, varscan2
- GPR149 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV67668052; called by muse, mutect2, varscan2
- GPR156 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100251104; called by muse, mutect2, varscan2
- GPR179 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs757517702; called by muse, mutect2, varscan2
- GPR52 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99267551; called by muse, mutect2, varscan2
- GPX3 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100161095; called by muse, mutect2, varscan2
- GREB1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52198465; called by muse, mutect2, varscan2
- GRIK3 | c.1998G>A p.M666I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757365724, COSV100901285; called by muse, mutect2, varscan2
- GRIN1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV100159786; called by muse, mutect2, varscan2
- GRIN2A | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV58021494; called by muse, mutect2, varscan2
- GRM7 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100735592, COSV63149931; called by muse, mutect2, varscan2
- GRXCR1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as COSV67669920; called by muse, mutect2, varscan2
- GSE1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV99496002; called by muse, mutect2, varscan2
- GUCY2C | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.324); catalogued as COSV53797507; called by muse, varscan2
- GUCY2C | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99663213, COSV99663552; called by muse, mutect2, varscan2
- HARBI1 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV100454685; called by muse, mutect2, varscan2
- HCAR3 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100811443; called by muse, mutect2, varscan2
- HCFC1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV60069835; called by muse, mutect2, varscan2
- HDAC4 | c.3083G>A p.W1028* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100612639; called by muse, mutect2, varscan2
- HDAC9 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67781502; called by muse, mutect2, varscan2
- HDAC9 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777828245, COSV67770295; called by muse, mutect2, varscan2
- HECTD4 | c.5018C>T p.T1673I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101106681; called by muse, mutect2, varscan2
- HECW1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748846572, COSV67825353; called by muse, mutect2, varscan2
- HIP1 | c.1492A>T p.M498L | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100416907; called by muse, mutect2, varscan2
- HIPK3 | c.1798G>C p.V600L | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV100305364; called by muse, mutect2, varscan2
- HIVEP1 | c.6323G>A p.R2108Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV65104977; called by muse, mutect2, varscan2
- HMGCS2 | c.105-1G>A p.X35_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as rs761008285, COSV101024678; called by muse, varscan2
- HNF1B | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757508365; called by muse, mutect2, varscan2
- HOMEZ | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1187862477, COSV100664022; called by muse, mutect2, varscan2
- HOXA7 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 152/226 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs770523270, COSV54217182; called by muse, mutect2, varscan2
- HOXB1 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.375); catalogued as rs766256495, COSV99495301; called by muse, mutect2, varscan2
- HYDIN | c.12538T>A p.L4180I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101124852; called by muse, mutect2
- HYDIN | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267604623, COSV55485377; called by muse, mutect2, varscan2
- ICAM3 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV99348863; called by muse, mutect2, varscan2
- IFI44 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV100877264; called by muse, mutect2, varscan2
- IGFL2 | c.221C>T p.P74L (on ENST00000377693 / NM_001135113.2; = p.P85L on NM_001002915.2) | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890647; called by muse, mutect2, varscan2
- IGHV3-16 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs545854019; called by muse, mutect2, varscan2
- IGKV3D-15 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.777); catalogued as rs1412468075; called by muse, mutect2, varscan2
- IGSF10 | c.2995A>G p.N999D | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99176604; called by muse, mutect2, varscan2
- IGSF6 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99193608; called by muse, mutect2, varscan2
- IL20RA | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.688); catalogued as COSV57358403; called by muse, mutect2, varscan2
- ILDR1 | c.1100G>A p.G367E (on ENST00000344209 / NM_001199799.2; = p.G323E on NM_175924.4) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs866370235, COSV56547877; called by muse, mutect2, varscan2
- INO80E | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV54232628; called by muse, mutect2, varscan2
- IPPK | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99845365; called by muse, mutect2, varscan2
- IQUB | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 84/114 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs267601258, COSV100226731; called by muse, mutect2, varscan2
- ISLR2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62301870; called by muse, mutect2, varscan2
- ITGA11 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757784144, COSV100240893; called by muse, mutect2, varscan2
- ITGA3 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as COSV99143233; called by muse, mutect2, varscan2
- ITGA8 | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV65224226; called by muse, mutect2, varscan2
- ITGB3 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV71383445; called by muse, mutect2, varscan2
- ITGB4 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99563317; called by muse, mutect2, varscan2
- ITGB8 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.379); catalogued as COSV56014211; called by muse, mutect2, varscan2
- ITLN1 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.287); catalogued as COSV100406118; called by muse, mutect2, varscan2
- ITPKC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs904288189, COSV54573896; called by muse, mutect2, varscan2
- IVL | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.558); catalogued as rs868067456, COSV64216199; called by muse, mutect2, varscan2
- IYD | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs963696189, COSV99989240, COSV99990193; called by muse, mutect2, varscan2
- KANK4 | c.2924C>T p.T975I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100443089, COSV99047138; called by muse, mutect2, varscan2
- KASH5 | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs1471046129, COSV101483387; called by muse, mutect2, varscan2
- KCNA10 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773174747, COSV63905362; called by muse, mutect2, varscan2
- KCNA7 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs762119570, COSV55503557; called by muse, mutect2, varscan2
- KCNJ16 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99387914; called by muse, mutect2, varscan2
- KCNMB1 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs754427970, COSV99210378; called by muse, mutect2, varscan2
- KCTD6 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100249985; called by muse, mutect2, varscan2
- KEL | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1474469148, COSV62338522; called by muse, mutect2, varscan2
- KHDC4 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as rs963607979, COSV100850765; called by muse, mutect2, varscan2
- KIF26B | c.3778C>T p.P1260S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.212); catalogued as COSV100831570; called by muse, mutect2
- KIF2B | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs199554010, COSV52131659, COSV99274477; called by muse, mutect2, varscan2
- KIR2DL3 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.398); catalogued as COSV100668155; called by muse, varscan2
- KL | c.3017A>T p.K1006I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV101198993; called by muse, mutect2, varscan2
- KMT2D | c.5071C>T p.P1691S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56491804; called by muse, mutect2, varscan2
- KMT2D | c.3982C>T p.R1328W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754797404, COSV56463794; ClinVar: uncertain significance; called by muse, varscan2
- KRT15 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99562873; called by muse, mutect2, varscan2
- KRT16 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV100052776; called by muse, mutect2
- KRT40 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898771; called by muse, mutect2, varscan2
- KRT74 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs769177339, COSV99977393; called by muse, mutect2, varscan2
- KRT75 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs760345998, COSV99359156; called by muse, mutect2, varscan2
- KRT76 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100195868; called by muse, mutect2, varscan2
- KRTAP13-3 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV100481707; called by muse, mutect2, varscan2
- LAIR1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.303); catalogued as COSV57310902; called by muse, mutect2, varscan2
- LAMA2 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250951882, COSV101369974, COSV101370385; called by muse, mutect2, varscan2
- LAMB1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 58/85 reads (68%) | catalogued as COSV99739830; called by muse, mutect2, varscan2
- LANCL2 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV54652666; called by muse, mutect2, varscan2
- LARP1B | c.2708G>A p.R903K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); catalogued as COSV99217758; called by muse, mutect2, varscan2
- LARP6 | c.411G>A p.K137= | Splice Region (SNP) | VAF 33/57 reads (58%) | catalogued as COSV100150673; called by muse, mutect2, varscan2
- LGR5 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1426192030, COSV57003027; called by muse, mutect2, varscan2
- LGR6 | c.214G>A p.D72N (on ENST00000367278 / NM_001017403.1; = p.D20N on NM_021636.3) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868398298, COSV99705990, COSV99706059; called by muse, mutect2, varscan2
- LGR6 | c.691G>A p.E231K (on ENST00000367278 / NM_001017403.1; = p.E179K on NM_021636.3) | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs546447981, COSV55164040; called by muse, mutect2, varscan2
- LGR6 | c.2111C>T p.P704L (on ENST00000367278 / NM_001017403.1; = p.P652L on NM_021636.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705993; called by muse, mutect2
- LIFR | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs373421600; called by muse, mutect2, varscan2
- LONRF1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101238171, COSV68037605; called by muse, mutect2, varscan2
- LOXL3 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99239429; called by muse, mutect2, varscan2
- LPA | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.924); catalogued as rs759880143, COSV60297449; called by muse, mutect2
- LRP1 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs905771676, COSV99674354; called by muse, mutect2, varscan2
- LRP1B | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1193614787, COSV101252209; called by muse, mutect2, varscan2
- LRP2 | c.11894G>A p.G3965E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV55539010; called by muse, mutect2, varscan2
- LRRC30 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV101274367; called by muse, mutect2, varscan2
- LRRC34 | c.829G>A p.D277N (on ENST00000446859 / NM_001172779.2; = p.D245N on NM_153353.5) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100336189; called by muse, mutect2, varscan2
- LRRC3B | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1486737127, COSV101185666, COSV101186084; called by muse, mutect2, varscan2
- LRRC7 | c.3335G>A p.R1112K (on ENST00000651989 / NM_001370785.2; = p.R1079K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as COSV99224386; called by muse, mutect2, varscan2
- LRRK1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV52610589; called by muse, mutect2, varscan2
- LRRTM4 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.885); catalogued as rs1008553397, COSV101298344; called by muse, mutect2, varscan2
- LRTM1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99835852; called by muse, mutect2, varscan2
- LTBP4 | c.4813C>T p.R1605C (on ENST00000308370 / NM_001042544.1; = p.R1568C on NM_003573.2) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as rs1245447833, COSV99180384; called by muse, mutect2, varscan2
- LY9 | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754794213, COSV99626177; called by muse, mutect2, varscan2
- LYPD3 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV54989696, COSV99746849; called by muse, mutect2, varscan2
- MAGI1 | c.2364A>C p.K788N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100439280; called by muse, mutect2, varscan2
- MAGI1 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100439282; called by muse, mutect2, varscan2
- MAGI1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV100439285; called by muse, mutect2, varscan2
- MAML3 | c.599T>G p.M200R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100504914; called by muse, mutect2, varscan2
- MAN1A1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100870577; called by muse, mutect2, varscan2
- MAP10 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.305); catalogued as COSV101406434, COSV101406542; called by muse, mutect2, varscan2
- MAP3K5 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100752461; called by muse, mutect2, varscan2
- MAPKBP1 | c.1060C>T p.P354S (on ENST00000456763 / NM_001128608.2; = p.P348S on NM_014994.3) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV52968593; called by muse, mutect2, varscan2
- MARCHF10 | c.1286A>C p.H429P | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100247823; called by muse, mutect2, varscan2
- MASP1 | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61827724; called by muse, mutect2, varscan2
- MDC1 | c.5395T>C p.F1799L | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100902529; called by muse, mutect2, varscan2
- MDC1 | c.5132C>T p.S1711F | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV64527220; called by muse, mutect2, varscan2
- MDH2 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782598079, COSV100242558; called by muse, mutect2, varscan2
- MED12L | c.5980G>A p.G1994S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as COSV99851461; called by muse, mutect2, varscan2
- MEGF10 | c.3317A>C p.H1106P | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99174701; called by muse, mutect2, varscan2
- MEN1 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53640117; called by muse, mutect2, varscan2
- MEP1A | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1386229821, COSV57919986; called by muse, mutect2, varscan2
- METTL4 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs1046783803, COSV100170461; called by muse, mutect2, varscan2
- MGAM | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs202247797, COSV71885480; called by muse, mutect2, varscan2
- MGAM | c.1558C>A p.Q520K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV101527367; called by muse, mutect2, varscan2
- MIA2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs1186969925, COSV54483868; called by muse, mutect2, varscan2
- MICAL3 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99259790; called by muse, mutect2, varscan2
- MIEF1 | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100307519; called by muse, mutect2, varscan2
- MIIP | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV52428346, COSV99337346; called by muse, mutect2
- MISP | c.1646G>A p.R549K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV99296574; called by muse, mutect2, varscan2
- MME | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV64706797; called by muse, mutect2, varscan2
- MME | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.393); catalogued as COSV100852228; called by muse, mutect2, varscan2
- MMEL1 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56519817, COSV99983219; called by muse, mutect2, varscan2
- MMP19 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100490958; called by muse, mutect2, varscan2
- MMP19 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs369065371; called by muse, mutect2, varscan2
- MMP24 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.863); catalogued as rs376734021, COSV55768997, COSV99864047; called by muse, mutect2, varscan2
- MOCS1 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.239); catalogued as rs762229041, COSV99224507; called by muse, mutect2, varscan2
- MOG | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100972959; called by muse, mutect2, varscan2
- MOGS | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99270254; called by muse, mutect2, varscan2
- MORC2 | c.2587G>C p.D863H (on ENST00000397641 / NM_001303256.3; = p.D801H on NM_014941.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV53198383, COSV99309443; called by muse, mutect2, varscan2
- MOXD1 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs751748575, COSV60950545; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV100824942, COSV64055959; called by muse, mutect2, varscan2
- MROH2B | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV68184700; called by muse, mutect2, varscan2
- MTG2 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100895124; called by muse, mutect2, varscan2
- MTRF1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65263341; called by muse, mutect2, varscan2
- MUC16 | c.42545A>T p.D14182V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.996); catalogued as COSV101109579; called by muse, mutect2, varscan2
- MUC16 | c.41455G>A p.E13819K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.915); catalogued as rs777014900, COSV101109580; called by muse, mutect2, varscan2
- MUC16 | c.36323G>A p.G12108D | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.069); catalogued as COSV67441313; called by muse, mutect2, varscan2
- MUC16 | c.28885C>T p.P9629S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.539); catalogued as rs267605787, COSV67466182; called by muse, mutect2, varscan2
- MUC16 | c.19199G>A p.R6400K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV67446917; called by muse, mutect2, varscan2
- MUC16 | c.17444C>T p.S5815F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV101198069; called by muse, mutect2, varscan2
- MUC16 | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs267605812, COSV101198070; called by muse, mutect2
- MUC17 | c.7843C>T p.P2615S | Missense Mutation (SNP) | VAF 322/483 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100071548; called by muse, mutect2, varscan2
- MYBL2 | c.498G>A p.G166= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99405991; called by muse, mutect2
- MYBPC1 | c.1448G>A p.G483E (on ENST00000550270 / NM_206820.2; = p.G508E on NM_002465.4) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62252714; called by muse, mutect2, varscan2
- MYBPC2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs377132992; called by muse, mutect2, varscan2
- MYBPC3 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs190765116, COSV99919877; ClinVar: likely benign / benign; called by muse, varscan2
- MYCT1 | c.112T>A p.F38I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100924025; called by muse, mutect2, varscan2
- MYCT1 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV65890738; called by muse, mutect2, varscan2
- MYH1 | c.4282G>A p.E1428K | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56858031; called by muse, mutect2, varscan2
- MYH8 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101238154; called by muse, mutect2, varscan2
- MYL7 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV99789905; called by muse, mutect2, varscan2
- MYO18A | c.5641C>T p.R1881W | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748567160, COSV100571906; called by muse, mutect2, varscan2
- MYO18B | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs566950878, COSV59126592; called by muse, mutect2, varscan2
- MYO3A | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761351165, COSV56323712, COSV99780626; called by muse, mutect2, varscan2
- MYO5B | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99543573; called by muse, mutect2, varscan2
- MYO7A | c.1395T>A p.F465L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV101289034; called by muse, mutect2, varscan2
- MYO7A | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782438837, COSV101289035; called by muse, mutect2, varscan2
- MYO9A | c.6607C>T p.R2203* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as rs1380363205, COSV100612598, COSV61848197; called by muse, mutect2, varscan2
- MYO9A | c.5159C>T p.S1720L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs554967460, COSV100613970; called by muse, mutect2
- MYOCD | c.2784T>A p.N928K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100590129; called by muse, mutect2, varscan2
- MYOM2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100036585; called by muse, mutect2, varscan2
- MYPN | c.3465T>A p.N1155K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100589508; called by muse, mutect2, varscan2
- MYT1L | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1209199727, COSV67735711; called by muse, mutect2, varscan2
- MZB1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100136347; called by muse, mutect2, varscan2
- NAA25 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs780387848, COSV99927253; called by muse, mutect2, varscan2
- NBL1 | c.281T>A p.I94N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV57030413, COSV99229309; called by muse, mutect2, varscan2
- NCKAP1L | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV53212973; called by muse, mutect2, varscan2
- NCKIPSD | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99583696; called by muse, mutect2, varscan2
- NCOA6 | c.3187C>T p.P1063S | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1404753457, COSV100749903; called by muse, mutect2, varscan2
- NDNF | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV65633560; called by muse, mutect2, varscan2
- NECTIN4 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100919807; called by muse, mutect2, varscan2
- NEDD1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99900733; called by muse, mutect2, varscan2
- NETO1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs374584848; called by muse, mutect2
- NETO1 | c.220+1G>A p.X74_splice | Splice Site (SNP) | VAF 16/33 reads (48%) | catalogued as COSV55009954; called by muse, mutect2, varscan2
- NEUROD4 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754528345, COSV99669698; called by muse, mutect2, varscan2
- NIPBL | c.3403C>T p.H1135Y | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV56961317, COSV99238667; called by muse, mutect2, varscan2
- NLRP13 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100738027; called by muse, mutect2, varscan2
- NLRP4 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs373819293; called by muse, mutect2, varscan2
- NLRP5 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV66766268; called by muse, mutect2, varscan2
- NLRP7 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1355632267, COSV60172417; called by muse, mutect2, varscan2
- NLRP7 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100051621; called by muse, mutect2, varscan2
- NLRP8 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs770878136, COSV52586706, COSV99404683; called by muse, mutect2, varscan2
- NMT2 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs149798719; called by muse, mutect2, varscan2
- NMUR2 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs200730009, COSV54918681; called by muse, mutect2, varscan2
- NOD1 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332114291, COSV99767771; called by muse, mutect2, varscan2
- NOL4 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV52344248; called by muse, mutect2
- NOMO3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99530650; called by muse, mutect2, varscan2
- NOP58 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99970426; called by muse, mutect2, varscan2
- NOTCH3 | c.4709G>C p.R1570P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99655779, COSV99659289; called by muse, mutect2, varscan2
- NPC1L1 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99202587; called by muse, mutect2, varscan2
- NPHP4 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100976713; called by muse, mutect2, varscan2
- NPHS2 | c.275-1G>A p.X92_splice | Splice Site (SNP) | VAF 16/34 reads (47%) | catalogued as CS141356, COSV100858118; called by muse, mutect2
- NR5A2 | c.590C>T p.S197F (on ENST00000367362 / NM_205860.3; = p.S151F on NM_003822.5) | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV99370631; called by muse, mutect2, varscan2
- NRG2 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866250848, COSV99179908; called by muse, mutect2, varscan2
- NTF4 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs1025529881, COSV56824622; called by muse, mutect2, varscan2
- NTPCR | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs759051611, COSV64052222; called by muse, mutect2, varscan2
- NXNL2 | c.156T>A p.Y52* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV101018218; called by muse, mutect2, varscan2
- NYAP2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99795684; called by muse, mutect2, varscan2
- OAS2 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV100660014; called by muse, mutect2, varscan2
- OBSCN | c.14503G>A p.V4835I | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99472165; called by muse, mutect2, varscan2
- OPALIN | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100959567; called by muse, mutect2, varscan2
- OR10H2 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1055546295, COSV100008615; called by muse, mutect2, varscan2
- OR10Q1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV100372145; called by muse, mutect2, varscan2
- OR10V1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100275541; called by muse, mutect2, varscan2
- OR11H12 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as rs759863247; called by mutect2, varscan2
- OR11H6 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59644265, COSV59645491; called by muse, mutect2, varscan2
- OR12D2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs1458564754, COSV65826259; called by muse, mutect2, varscan2
- OR13C4 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV52926173, COSV99470316; called by muse, mutect2, varscan2
- OR13C5 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs754228490, COSV66164428; called by muse, mutect2, varscan2
- OR13D1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100598636; called by muse, mutect2, varscan2
- OR1B1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs768082466, COSV100506394; called by muse, mutect2
- OR1C1 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs770473849, COSV101376157, COSV68715581; called by muse, mutect2, varscan2
- OR1L8 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs771093917, COSV59185779; called by muse, mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 68/377 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, varscan2
- OR2G2 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1289651797, COSV100189552; called by muse, mutect2, varscan2
- OR2T3 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as rs965513390, COSV100613141; called by muse, mutect2
- OR4C12 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267602935, COSV100078248; called by muse, mutect2, varscan2
- OR4D5 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100189718; called by muse, mutect2, varscan2
- OR4K5 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60002898; called by muse, mutect2, varscan2
- OR4M1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs778227156, COSV60060270; called by muse, mutect2, varscan2
- OR4Q3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV100056706; called by muse, mutect2, varscan2
- OR51S1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs142743963; called by muse, mutect2, varscan2
- OR51T1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs770458692, COSV59024616; called by muse, mutect2, varscan2
- OR52E2 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100384619, COSV100384683; called by muse, mutect2, varscan2
- OR52E6 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV61431349; called by muse, mutect2, varscan2
- OR52K1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV56903226; called by muse, mutect2, varscan2
- OR52N4 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100421565; called by muse, mutect2, varscan2
- OR56A3 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1364186139, COSV100290033; called by muse, mutect2, varscan2
- OR5AC2 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562786394, COSV100684561, COSV62279251; called by muse, mutect2, varscan2
- OR5D13 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV100686704; called by muse, mutect2, varscan2
- OR5H1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100641618; called by muse, mutect2, varscan2
- OR6C74 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as COSV59605754; called by muse, mutect2, varscan2
- OR6V1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867782093, COSV69237344; called by muse, mutect2, varscan2
- OR7D4 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100432581; called by muse, mutect2, varscan2
- OR8B2 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.356); catalogued as COSV100899308; called by muse, mutect2, varscan2
- OR9A2 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV100628159; called by muse, mutect2, varscan2
- OR9K2 | c.577T>A p.F193I (on ENST00000305377; = p.F171I on NM_001005243.1) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100543732; called by muse, mutect2, varscan2
- OTOGL | c.3917G>A p.R1306K (on ENST00000547103; = p.R1297K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101509016; called by muse, mutect2, varscan2
- P3H2 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1339275479, COSV100076987; called by muse, mutect2, varscan2
- PADI1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs760951556, COSV64938943; called by muse, mutect2, varscan2
- PADI3 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV64935180; called by muse, mutect2, varscan2
- PAPLN | c.3355G>T p.D1119Y (on ENST00000554301; = p.D1092Y on NM_173462.4) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV99389007, COSV99390070; called by muse, mutect2, varscan2
- PAPPA | c.3274C>G p.Q1092E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100072818, COSV100073108; called by muse, mutect2, varscan2
- PARP11 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs377497123; called by muse, mutect2, varscan2
- PCDH10 | c.1550C>G p.S517C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99992923; called by muse, mutect2, varscan2
- PCDHAC1 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53838602, COSV53862217; called by muse, mutect2, varscan2
- PCDHB1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.265); catalogued as COSV100128017; called by muse, mutect2, varscan2
- PCDHB10 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as COSV99503619; called by muse, mutect2, varscan2
- PCDHB2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.158); catalogued as COSV99522789, COSV99523365; called by muse, mutect2, varscan2
- PCDHB2 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52031260; called by muse, mutect2, varscan2
- PCDHB3 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); catalogued as COSV50635206; called by muse, mutect2, varscan2
- PCDHB7 | c.1877C>T p.T626I | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1226284588, COSV99175574; called by muse, mutect2, varscan2
- PCDHB8 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 59/526 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99175575; called by muse, mutect2, varscan2
- PCDHGA2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53905586; called by muse, mutect2, varscan2
- PCLO | c.12545C>T p.A4182V | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100427232; called by muse, mutect2, varscan2
- PCSK5 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100949447; called by muse, mutect2, varscan2
- PDE1C | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 114/166 reads (69%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); catalogued as rs867845896, COSV58523820; called by muse, mutect2, varscan2
- PDE8B | c.797+2T>A p.X266_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99366098; called by muse, mutect2, varscan2
- PDS5B | c.4244G>A p.G1415D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV100220448; called by muse, mutect2, varscan2
- PEG3 | c.4733C>T p.S1578F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327890443, COSV99687183; called by muse, mutect2, varscan2
- PGLYRP4 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV100668301; called by muse, mutect2, varscan2
- PHACTR2 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754354729, COSV99990981; called by muse, mutect2, varscan2
- PHACTR3 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100732195; called by muse, mutect2, varscan2
- PICALM | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100707707; called by muse, mutect2, varscan2
- PIGB | c.1627A>C p.K543Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99380007; called by muse, mutect2, varscan2
- PIK3C2G | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV56819923; called by muse, mutect2, varscan2
- PILRA | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99546269; called by muse, mutect2, varscan2
- PITPNM1 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV100711541; called by muse, mutect2, varscan2
- PKHD1L1 | c.9709G>A p.E3237K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV65750419; called by muse, mutect2, varscan2
- PKHD1L1 | c.9946G>A p.D3316N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV101005312; called by muse, mutect2, varscan2
- PKP2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV50740851; called by muse, mutect2, varscan2
- PLAG1 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100387690; called by muse, mutect2, varscan2
- PLCB1 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62071995; called by muse, mutect2, varscan2
- PLCB1 | c.3637G>A p.D1213N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV62058192; called by muse, mutect2
- PLCL2 | c.2542C>T p.P848S (on ENST00000615277 / NM_001144382.2; = p.P722S on NM_015184.5) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV67622298; called by muse, mutect2, varscan2
- PLCZ1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1308051972, COSV56855967; called by muse, mutect2, varscan2
- PLCZ1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs779427460, COSV56848630; called by muse, mutect2, varscan2
- PLXDC2 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs368244668, COSV65900642; called by muse, mutect2, varscan2
- PLXNB3 | c.2272C>T p.Q758* | Nonsense Mutation (SNP) | VAF 21/29 reads (72%) | catalogued as COSV100737092; called by muse, mutect2, varscan2
- PNPLA6 | c.1337C>T p.S446F (on ENST00000414982 / NM_001166111.2; = p.S398F on NM_006702.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs1251079199, COSV99653089; called by muse, mutect2, varscan2
- POLR1B | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637058; called by muse, mutect2, varscan2
- POLR1E | c.517C>T p.P173S (on ENST00000377792 / NM_001282766.1; = p.P111S on NM_022490.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100905389; called by muse, mutect2, varscan2
- POTEA | c.1159C>T p.P387S (on ENST00000519951 / NM_001005365.2; = p.P341S on NM_001002920.1) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as rs1474244351; called by muse, mutect2, varscan2
- POTEF | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as rs761290085, COSV99051461; called by muse, mutect2, varscan2
- POU5F1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99462704; called by muse, mutect2, varscan2
- PPBP | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99932987; called by muse, mutect2, varscan2
- PPFIA2 | c.2920C>T p.R974* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV61041582; called by muse, mutect2, varscan2
- PPP1R26 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100777986; called by muse, mutect2, varscan2
- PPP1R42 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100221023, COSV61207368; called by muse, mutect2, varscan2
- PPP1R9A | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748503389, COSV56895023; called by muse, mutect2
- PPP2R2C | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100065909, COSV100067021; called by muse, mutect2, varscan2
- PPP2R5E | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518287, COSV61743667; called by muse, mutect2, varscan2
- PPP4R3B | c.581T>G p.L194W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701363; called by muse, mutect2, varscan2
- PRB4 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); catalogued as rs1330829517, COSV54397550; called by muse, mutect2, varscan2
- PRDM8 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs902909826, COSV100324910; called by muse, mutect2, varscan2
- PRDM8 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs763341696, COSV100324913; called by muse, mutect2, varscan2
- PREX2 | c.4115G>A p.G1372E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55750307; called by muse, mutect2, varscan2
- PRF1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100942516; called by muse, mutect2, varscan2
- PRMT5 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53546781; called by muse, mutect2, varscan2
- PROM2 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100468622; called by muse, mutect2, varscan2
- PRPSAP2 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99264318; called by muse, mutect2, varscan2
- PRRC1 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV99687583; called by muse, mutect2, varscan2
- PRSS35 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV100864028; called by muse, mutect2, varscan2
- PSG7 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.373); catalogued as rs151272638, COSV68444408; called by muse, mutect2, varscan2
- PTCH2 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs376282577; called by muse, mutect2, varscan2
- PTGER3 | c.1081G>A p.E361K (on ENST00000628037 / NM_198717.2; = p.E370K on NM_198716.2) | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs771757558, COSV63388000; called by muse, mutect2, varscan2
- PTK2B | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs921254529, COSV57752408; called by muse, mutect2, varscan2
- PTK7 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.3); catalogued as COSV100029816; called by muse, mutect2, varscan2
- PTPN2 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs754147924, COSV100518321; called by muse, mutect2, varscan2
- PTPRB | c.3842G>A p.W1281* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as COSV54232440; called by muse, mutect2, varscan2
- PTPRD | c.4633G>A p.D1545N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs144763077; called by muse, mutect2, varscan2
- PTPRD | c.4073C>T p.S1358F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201031030, COSV61941464; called by mutect2, varscan2
- PTPRG | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99872783; called by muse, mutect2, varscan2
- PTPRZ1 | c.6490A>G p.K2164E | Missense Mutation (SNP) | VAF 83/111 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as rs1407148668, COSV101099476; called by muse, mutect2, varscan2
- PYCR1 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1219327272, COSV57999536; called by muse, mutect2, varscan2
- RABL6 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.728); catalogued as rs370482677; called by muse, varscan2
- RAD21 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV52063755; called by muse, mutect2, varscan2
- RAD50 | c.3745C>A p.L1249M | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528577; called by muse, mutect2, varscan2
- RAD51AP2 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.31); catalogued as COSV101208282, COSV104433749; called by muse, mutect2, varscan2
- RAI1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.204); catalogued as COSV99883301; called by muse, mutect2, varscan2
- RAPGEF5 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV59780378; called by muse, mutect2
- RBM27 | c.179-1G>A p.X60_splice | Splice Site (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99505648; called by muse, mutect2, varscan2
- RDH12 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs115356583, COSV50821547; called by muse, mutect2, varscan2
- REC8 | c.1445T>C p.V482A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.21); catalogued as COSV100268856; called by muse, mutect2, varscan2
- REEP4 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs760630362, COSV57942484; called by muse, mutect2, varscan2
- RESF1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV57025381; called by muse, mutect2, varscan2
- RESF1 | c.4054T>C p.S1352P | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100440081; called by muse, mutect2, varscan2
- RHCG | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99174053; called by muse, mutect2, varscan2
- RHOBTB1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558314; called by muse, mutect2, varscan2
- RNF112 | c.1192dup p.Q398Pfs*4 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | catalogued as rs779219461; called by mutect2, varscan2
- RNF17 | c.612G>A p.R204= | Splice Region (SNP) | VAF 13/68 reads (19%) | catalogued as COSV55037445; called by muse, mutect2, varscan2
- RNF17 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99692110; called by muse, mutect2
- ROBO2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs567065372, COSV59896989; called by muse, mutect2, varscan2
- ROBO2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59915465; called by muse, mutect2, varscan2
- ROR1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV100934903; called by muse, varscan2
- ROR1 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs776549301, COSV100934904; called by muse, mutect2, varscan2
- ROS1 | c.5249C>T p.A1750V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs768835741, COSV100876414, COSV100877723; called by muse, mutect2, varscan2
- ROS1 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as rs747794595, COSV63853737; called by muse, mutect2, varscan2
- RP1 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV99606238; called by muse, mutect2, varscan2
- RP1 | c.2461C>T p.H821Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV55111203; called by muse, mutect2, varscan2
- RP1L1 | c.6367G>A p.G2123R | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs757772383, COSV101222931; called by muse, mutect2, varscan2
- RPS21 | c.52T>A p.S18T | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV99652947; called by muse, mutect2, varscan2
- RRP1B | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342574440, COSV61478465; called by muse, mutect2, varscan2
- RSPO3 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV100759463; called by muse, mutect2, varscan2
- RTP1 | c.240G>A p.W80* | Nonsense Mutation (SNP) | VAF 37/70 reads (53%) | catalogued as COSV56618164; called by muse, mutect2, varscan2
- RTTN | c.5034T>G p.V1678= | Splice Region (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99730971; called by muse, mutect2
- SAGE1 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100186614; called by muse, mutect2, varscan2
- SALL3 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs569636624, COSV101609931; called by muse, mutect2, varscan2
- SAMD3 | c.654C>T p.F218= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as rs766792443, COSV60775773; called by muse, mutect2, varscan2
- SAMD9L | c.929T>A p.I310N | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100560300; called by muse, mutect2, varscan2
- SBF1 | c.4774G>C p.V1592L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1020594214, COSV100817432; called by muse, mutect2, varscan2
- SCGN | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760647578, COSV58546220; called by muse, mutect2, varscan2
- SCN11A | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778518459, COSV56568512; called by muse, mutect2, varscan2
- SCN3B | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs764587765, COSV54798916; called by muse, mutect2, varscan2
- SCN5A | c.1838C>T p.S613F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV100346437; called by muse, varscan2
- SCN5A | c.1778G>A p.S593N | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as COSV100346441; called by muse, varscan2
- SCP2 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101026805; called by muse, mutect2, varscan2
- SEC63 | c.253T>A p.L85M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV100938303; called by muse, mutect2, varscan2
- SELENOP | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62791893; called by muse, mutect2, varscan2
- SEMA6D | c.3014C>T p.T1005I (on ENST00000316364 / NM_153618.2; = p.T943I on NM_020858.2) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV100316401; called by muse, mutect2, varscan2
- SERGEF | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.298); catalogued as COSV56387998; called by muse, mutect2, varscan2
- SERPINA7 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 71/97 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV100568205, COSV59666818; called by muse, mutect2, varscan2
- SGK2 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100414550; called by muse, mutect2, varscan2
- SH3BP5L | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs1341232177, COSV100821958; called by muse, mutect2, varscan2
- SH3RF2 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as rs1026700332, COSV100767588; called by muse, mutect2, varscan2
- SH3RF2 | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV100767539; called by muse, mutect2, varscan2
- SHCBP1L | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100840928; called by muse, mutect2, varscan2
- SHLD2 | c.2309T>C p.V770A | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100078831; called by muse, mutect2, varscan2
- SHPRH | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV99261227; called by muse, mutect2, varscan2
- SI | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100013882, COSV100014430, COSV52265616; called by muse, mutect2, varscan2
- SIAE | c.1308_1310del p.N436del | In Frame Del (DEL) | VAF 22/38 reads (58%) | catalogued as rs752182375; called by pindel, varscan2
- SIM1 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.714); catalogued as rs992400910, COSV53493167; called by muse, mutect2, varscan2
- SIM1 | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.398); catalogued as rs770641539, COSV53495593; called by muse, mutect2, varscan2
- SIX6 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100576431; called by muse, mutect2, varscan2
- SKAP1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs573034197, COSV61143949; called by muse, mutect2
- SLA | c.631C>T p.P211S (on ENST00000338087 / NM_001045556.3; = p.P251S on NM_006748.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55067413, COSV99598954; called by muse, varscan2
- SLAIN1 | c.1043G>A p.G348E (on ENST00000466548; = p.G85E on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV99934950; called by muse, mutect2, varscan2
- SLAMF7 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100833189; called by muse, mutect2, varscan2
- SLC13A2 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100120078; called by muse, mutect2, varscan2
- SLC16A9 | c.1180A>C p.S394R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV101264302; called by muse, mutect2, varscan2
- SLC25A47 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV100836443; called by muse, mutect2, varscan2
- SLC25A48 | c.539G>A p.G180E (on ENST00000650267; = p.G126E on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99191937; called by muse, mutect2, varscan2
- SLC2A5 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.338); catalogued as COSV101072617; called by muse, mutect2, varscan2
- SLC34A3 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100746603; called by muse, mutect2, varscan2
- SLC35F6 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733592; called by muse, mutect2, varscan2
- SLC5A11 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100762663, COSV61742091; called by muse, varscan2
- SLC6A4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV55567150; called by muse, mutect2, varscan2
- SLC8A1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60494202, COSV60497847; called by muse, mutect2, varscan2
- SLC8A1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV60493161; called by muse, mutect2, varscan2
- SLC9A4 | c.2186G>A p.R729K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99762567, COSV99762662, COSV99762680; called by muse, mutect2, varscan2
- SLC9C2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); catalogued as COSV100876554; called by muse, mutect2, varscan2
- SLCO1A2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV100261305; called by muse, mutect2, varscan2
- SLCO6A1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112814311, COSV65810757; called by muse, mutect2, varscan2
- SLIT1 | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820563; called by muse, mutect2, varscan2
- SLITRK3 | c.2176A>G p.T726A | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs762445041, COSV99578479; called by muse, mutect2, varscan2
- SLITRK5 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100280256; called by muse, mutect2, varscan2
- SMOC1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs764482616, COSV62759427; called by muse, mutect2, varscan2
- SNCAIP | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs866990849, COSV54424177; called by muse, mutect2, varscan2
- SNRNP27 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99731974; called by muse, mutect2, varscan2
- SNX13 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1232354761, COSV101296780; called by muse, mutect2, varscan2
- SOX30 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99398138; called by muse, mutect2, varscan2
- SP100 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs1472834401, COSV50987020; called by muse, mutect2, varscan2
- SPACA1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV52759719, COSV52759965; called by muse, mutect2, varscan2
- SPCS1 | c.302T>C p.V101A (on ENST00000233025; = p.V34A on NM_014041.5) | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV99236732; called by muse, mutect2, varscan2
- SPEF2 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213588; called by muse, mutect2, varscan2
- SPHKAP | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100763671; called by muse, mutect2, varscan2
- SPICE1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as rs755371412, COSV99870836; called by muse, mutect2, varscan2
- SPINK6 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100347040; called by muse, mutect2, varscan2
- SPINT1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs781044211, COSV100688874; called by muse, mutect2, varscan2
- SPPL2B | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV101476097; called by muse, mutect2, varscan2
- SPPL2C | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100233924; called by muse, mutect2, varscan2
- SPPL2C | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756471815, COSV100233927; called by muse, mutect2, varscan2
- SPRR1A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs759863345, COSV100200988; called by muse, mutect2, varscan2
- SRSF3 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs142398173, COSV59670606, COSV59671543; called by muse, mutect2, varscan2
- ST6GAL2 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | PolyPhen benign (0.005); catalogued as COSV64530926, COSV64533336; called by muse, mutect2, varscan2
- ST7L | c.426T>G p.N142K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100573632; called by muse, mutect2, varscan2
- STAB1 | c.7234G>A p.G2412S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100194506; called by muse, mutect2, varscan2
- STAC | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56212800, COSV99829453; called by muse, mutect2, varscan2
- STARD13 | c.2266C>T p.L756F (on ENST00000336934 / NM_001243476.3; = p.L638F on NM_052851.3) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715438; called by muse, mutect2, varscan2
- STAT4 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.858); catalogued as COSV100635942; called by muse, mutect2
- STC1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.175); catalogued as COSV51687989; called by muse, mutect2, varscan2
- STXBP5L | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs561846083, COSV56522382; called by muse, mutect2, varscan2
- SV2A | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64964404, COSV64964868; called by muse, mutect2, varscan2
- SV2C | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100455618; called by muse, mutect2, varscan2
- SVEP1 | c.6413C>T p.S2138F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV99928240; called by muse, mutect2, varscan2
- SYK | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65327359; called by muse, mutect2
- SYNE1 | c.3130C>T p.R1044* (on ENST00000367255 / NM_182961.4; = p.R1051* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as rs757719808, COSV54920772, COSV54924065; called by muse, mutect2, varscan2
- TAF1L | c.5021C>T p.S1674F | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs766996879, COSV54271737; called by muse, mutect2, varscan2
- TAF1L | c.3830C>T p.P1277L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV99643997; called by muse, mutect2, varscan2
- TAF1L | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99644076; called by muse, mutect2, varscan2
- TAF3 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV100719808, COSV60204983; called by muse, mutect2, varscan2
- TAS1R2 | c.2312C>T p.T771I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.175); catalogued as rs1299710523, COSV100946131; called by muse, mutect2, varscan2
- TBC1D21 | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100311154; called by muse, mutect2, varscan2
- TBC1D4 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs751499017, COSV100884519, COSV66487696; called by muse, mutect2, varscan2
- TBCD | c.2881G>C p.A961P | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100832571; called by muse, mutect2, varscan2
- TBCD | c.2882C>A p.A961E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100832573, COSV100833691; called by muse, mutect2, varscan2
596 further variants in this file (152 protein-altering or splice-affecting, 413 silent, 31 other) are not listed here.
